Somatic mutation profile of tumor specimen TCGA-ZB-A96A-01A (aliquot TCGA-ZB-A96A-01A-11D-A428-09) from TCGA case TCGA-ZB-A96A, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 53.2 years (19,424 days).
Specimen TCGA-ZB-A96A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbf8ceb4-1027-4b29-85a2-e95541720f30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A96A-10A (Blood Derived Normal), aliquot TCGA-ZB-A96A-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28afaca0-e5c5-4f04-a348-59d2fd7f1887

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 31/374 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- ITM2A | c.440del p.K147Rfs*3 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs36103089; called by pindel, varscan2
- SCNN1D | c.548C>T p.P183L (on ENST00000338555; = p.P347L on NM_001130413.4) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.586); catalogued as rs543238689; called by mutect2, varscan2
- ZNF559-ZNF177 | c.127A>G p.M43V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58673325; called by muse, mutect2, varscan2
- ACY3 | c.743_744insT p.Q248Hfs*26 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by muse*, mutect2, varscan2*
- MEIOB | c.1298G>A p.S433N | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.835); called by muse, mutect2
- SETD1A | c.341G>T p.C114F | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
